FM case AD13494 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/8255afc4-1213-44f4-8ca7-d1185b361489

Female, 70.6 years: Infiltrating duct carcinoma, NOS (ICD-O-3 8500/3) of the breast; metastasis biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
